Somatic mutation profile of tumor specimen TCGA-BR-8485-01A (aliquot TCGA-BR-8485-01A-11D-2394-08) from TCGA case TCGA-BR-8485, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 68.0 years (24,845 days).
Specimen TCGA-BR-8485-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa0295d7-7159-44cb-ae3f-f1bdd7f81276.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8485-10A (Blood Derived Normal), aliquot TCGA-BR-8485-10A-01D-2394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48868807-52b7-4af1-94ea-8f5d2b29c6f6

The open-access MAF lists 335 somatic variants for this specimen: 256 protein-altering or splice-affecting, 73 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 234, Silent 73, Nonsense Mutation 7, Frame Shift Del 4, Splice Region 3, Intron 3, Splice Site 3, RNA 3, Frame Shift Ins 2, Nonstop Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TENT5D | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 15/73 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- ABCA12 | c.3455C>T p.S1152L (on ENST00000272895 / NM_173076.3; = p.S834L on NM_015657.3) | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753433213, COSV55948030; called by muse, mutect2, varscan2
- ABCA13 | c.2820A>C p.E940D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.93); catalogued as COSV70025519, COSV70028233; called by muse, mutect2, varscan2
- ABCA13 | c.3869A>C p.E1290A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.093); catalogued as COSV70025522; called by muse, mutect2, varscan2
- ABCC12 | c.431T>G p.L144R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60911250; called by muse, mutect2
- ABCC9 | c.2101A>C p.T701P | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53961556; called by muse, mutect2, varscan2
- ACVR2B | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as COSV61700939; called by muse, mutect2, varscan2
- ADAMTS12 | c.2199A>C p.E733D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61254576; called by muse, mutect2, varscan2
- ADAMTS18 | c.990A>C p.K330N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51398266; called by muse, mutect2, varscan2
- ADAMTS20 | c.1303A>C p.S435R | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV67125648; called by muse, varscan2
- ADGRE2 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV59691349; called by muse, mutect2, varscan2
- ADGRL2 | c.3140T>A p.L1047H (on ENST00000370717 / NM_001366005.1; = p.L1034H on NM_012302.4) | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54649767; called by muse, mutect2, varscan2
- ADGRV1 | c.3917G>C p.G1306A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV67977534; called by muse, mutect2, varscan2
- ADGRV1 | c.13514T>C p.I4505T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV67977542; called by muse, mutect2, varscan2
- AGBL1 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.049); catalogued as rs372186294, COSV66874000; called by muse, mutect2, varscan2
- AMPH | c.1272+2T>C p.X424_splice | Splice Site (SNP) | VAF 39/141 reads (28%) | catalogued as COSV57731332; called by muse, mutect2, varscan2
- ANO3 | c.2143T>C p.L715= | Splice Region (SNP) | VAF 32/89 reads (36%) | catalogued as rs1054744317, COSV56778539; called by muse, mutect2, varscan2
- ARFGEF3 | c.1435T>G p.F479V | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as COSV52449278; called by muse, mutect2, varscan2
- ARHGAP28 | c.925G>A p.E309K (on ENST00000383472 / NM_001366230.1; = p.E150K on NM_001010000.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51630689; called by muse, mutect2, varscan2
- ARHGEF6 | c.2331A>C p.*777Yext*15 | Nonstop Mutation (SNP) | VAF 22/88 reads (25%) | catalogued as COSV51687158; called by muse, varscan2
- ARL5B | c.231G>C p.W77C | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66010778; called by muse, mutect2, varscan2
- ATP2B3 | c.3259G>A p.E1087K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.211); catalogued as rs897119876, COSV54839489; called by muse, mutect2, varscan2
- ATXN2 | c.1375G>A p.A459T (on ENST00000550104; = p.A299T on NM_002973.4) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66480926; called by muse, mutect2, varscan2
- AURKC | c.125A>G p.D42G (on ENST00000302804 / NM_001015878.2; = p.D8G on NM_003160.3) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57136734; called by muse, mutect2, varscan2
- BBS9 | c.2069C>T p.A690V (on ENST00000242067 / NM_001348036.1; = p.A650V on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1488623911, COSV54154945; called by muse, mutect2, varscan2
- C1QTNF2 | c.796C>T p.R266W (on ENST00000393975; = p.R221W on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1228642213, COSV67432332; called by muse, mutect2, varscan2
- CACNA1F | c.3467A>C p.N1156T | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59902797; called by muse, mutect2, varscan2
- CADM3 | c.608A>G p.D203G (on ENST00000368125 / NM_001127173.3; = p.D237G on NM_021189.5) | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63683503; called by muse, mutect2, varscan2
- CAMTA1 | c.1447T>G p.F483V | Missense Mutation (SNP) | VAF 48/157 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57879577; called by muse, mutect2, varscan2
- CARD18 | c.200A>G p.K67R | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV73233129; called by muse, mutect2, varscan2
- CBLN2 | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 31/120 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54050077, COSV54052757, COSV54053612; called by muse, mutect2, varscan2
- CCDC180 | c.3510A>C p.E1170D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.131); catalogued as COSV63826372; called by muse, mutect2, varscan2
- CCDC42 | c.350T>C p.L117P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.961); catalogued as COSV53447930; called by muse, mutect2, varscan2
- CCDC50 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66667006; called by muse, mutect2, varscan2
- CCNB3 | c.535A>C p.K179Q | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); catalogued as COSV52069448, COSV52075377; called by muse, mutect2, varscan2
- CEP350 | c.578T>G p.V193G | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV62485613; called by muse, mutect2, varscan2
- CEP350 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV62598401; called by muse, mutect2, varscan2
- CNOT8 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs759958959, COSV53584955; called by muse, mutect2, varscan2
- CNPY4 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 38/101 reads (38%) | catalogued as rs1477095982, COSV53541857; called by muse, mutect2, varscan2
- COL12A1 | c.8456T>C p.L2819P | Missense Mutation (SNP) | VAF 11/266 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV100486401, COSV59388613; called by muse, mutect2
- COL19A1 | c.521T>A p.L174H | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59564296; called by muse, mutect2, varscan2
- COL1A2 | c.2524T>G p.F842V | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV51952331; called by muse, mutect2, varscan2
- COL21A1 | c.1637T>C p.F546S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.396); catalogued as COSV55152285; called by muse, mutect2, varscan2
- COL28A1 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201662547, COSV68080306; called by muse, mutect2, varscan2
- COL5A1 | c.4463T>G p.I1488S | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV65664537; called by muse, mutect2, varscan2
- CRB1 | c.1721T>G p.F574C | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV66328509; called by muse, mutect2, varscan2
- CTNND2 | c.2617T>G p.L873V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58877880, COSV58910673; called by muse, mutect2, varscan2
- CUBN | c.6136T>G p.L2046V | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs1425767211, COSV64706900, COSV64707965; called by muse, mutect2, varscan2
- CYFIP2 | c.2792A>C p.N931T (on ENST00000616178 / NM_001291722.2; = p.N906T on NM_014376.4) | Missense Mutation (SNP) | VAF 33/191 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV59026934; called by muse, mutect2, varscan2
- CYLC1 | c.248A>C p.K83T | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV61409586; called by muse, mutect2
- DCDC1 | c.2708T>G p.L903R (on ENST00000597505 / NM_001367979.1; = p.L10R on NM_020869.3) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100338031; called by muse, mutect2, varscan2
- DECR1 | c.494C>G p.T165S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55166478; called by muse, mutect2, varscan2
- DENND4C | c.5874T>G p.I1958M (on ENST00000434457 / NM_001330640.2; = p.I1909M on NM_017925.7) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV59547428; called by muse, mutect2, varscan2
- DKK1 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV64759883; called by muse, mutect2
- DMD | c.5861A>G p.K1954R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.081); catalogued as COSV63732565; called by muse, mutect2, varscan2
- DMD | c.4088A>C p.K1363T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.059); catalogued as COSV63732568, COSV63756777; called by muse, mutect2, varscan2
- DNAH11 | c.2156A>C p.N719T | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60937264; called by muse, mutect2, varscan2
- DNAH3 | c.10072T>C p.Y3358H | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54501128; called by muse, mutect2, varscan2
- DNAH5 | c.12599A>G p.K4200R | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54201514, COSV54202045, COSV54212456; called by muse, mutect2, varscan2
- DNAH5 | c.11069T>G p.F3690C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54201529; called by muse, mutect2, varscan2
- DNAH5 | c.6485T>G p.L2162R | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54201539; called by muse, mutect2, varscan2
- DNAH5 | c.4571T>G p.L1524R | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV54201584; called by muse, mutect2, varscan2
- DOCK4 | c.4563A>C p.Q1521H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV70233020; called by muse, mutect2, varscan2
- DOK5 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs1568781559, COSV52815932; called by muse, mutect2, varscan2
- DRD2 | c.52T>C p.W18R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.174); catalogued as COSV60753724; called by muse, mutect2, varscan2
- E2F7 | c.878A>C p.K293T | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755396047, COSV59736560; called by muse, mutect2, varscan2
- EMB | c.555T>G p.C185W | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.855); catalogued as COSV57480105; called by muse, mutect2, varscan2
- EPHA6 | c.971T>A p.V324D | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67556869; called by muse, mutect2, varscan2
- ERBB4 | c.3488T>C p.L1163P | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs768312275, COSV61458785; called by muse, mutect2, varscan2
- ERICH3 | c.671T>G p.L224R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58598347; called by muse, mutect2, varscan2
- EVC2 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV60387219; called by muse, mutect2, varscan2
- FAM13C | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53242365; called by muse, mutect2, varscan2
- FAM153A | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs750905945, COSV62362244; called by muse, varscan2
- FAM8A1 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1366000323, COSV52580283, COSV52580559; called by muse, mutect2
- FBXW7 | c.1072C>T p.Q358* (on ENST00000281708 / NM_001349798.2; = p.Q278* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 38/67 reads (57%) | catalogued as COSV55891095; called by muse, mutect2, varscan2
- FERD3L | c.44A>G p.D15G | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV51761408; called by muse, mutect2, varscan2
- FLNA | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs374295965, COSV61036339; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- FMN2 | c.4062A>C p.K1354N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV60415005; called by muse, mutect2, varscan2
- FSHR | c.900A>C p.E300D | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV58616635, COSV58628216; called by muse, mutect2
- GAB3 | c.841A>C p.S281R | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV65818725; called by muse, mutect2, varscan2
- GLI3 | c.2795A>C p.K932T | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV67884670; called by muse, mutect2, varscan2
- GPR173 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.074); catalogued as COSV60233086; called by muse, mutect2, varscan2
- GRM5 | c.2716A>C p.T906P | Missense Mutation (SNP) | VAF 70/325 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.282); catalogued as COSV59588196; called by muse, mutect2, varscan2
- GTDC1 | c.647A>C p.K216T | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.04); catalogued as COSV53987536; called by muse, mutect2
- GYPE | c.18C>G p.I6M | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as COSV100679219, COSV62261384; called by muse, mutect2, varscan2
- HCN1 | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57491152; called by muse, varscan2
- HGF | c.1301A>C p.K434T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.762); catalogued as COSV55944784, COSV55953381; called by muse, mutect2, varscan2
- HMCN1 | c.13538A>C p.N4513T | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54873359; called by muse, mutect2, varscan2
- IGF2R | c.629A>T p.N210I | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625995; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.247T>C p.F83L | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.33); catalogued as rs771126486; called by muse, mutect2, varscan2
- KCNA4 | c.952T>A p.L318I | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as COSV100068452, COSV60250374; called by muse, mutect2, varscan2
- KCNB2 | c.140A>G p.E47G | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73048718; called by muse, mutect2, varscan2
- KCNJ3 | c.163G>C p.V55L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV54530658, COSV54530680, COSV54531250; called by muse, mutect2, varscan2
- KCNJ8 | c.692A>C p.K231T | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV53715083; called by muse, mutect2, varscan2
- KCNT2 | c.223T>G p.L75V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV54062150; called by muse, mutect2, varscan2
- KDM4D | c.1572A>C p.*524Yext*29 | Nonstop Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV58633445; called by muse, varscan2
- KLHL1 | c.1685A>C p.D562A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64766062; called by muse, mutect2, varscan2
- KMT2A | c.11893C>T p.R3965W | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63281245; called by muse, mutect2
- KMT2E | c.4871C>T p.A1624V | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as COSV57569012; called by muse, mutect2, varscan2
- LAMA3 | c.9277A>C p.S3093R (on ENST00000313654 / NM_198129.4; = p.S1484R on NM_000227.6) | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.041); catalogued as COSV52529029; called by muse, mutect2, varscan2
- LIF | c.129C>A p.N43K | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99969815; called by muse, mutect2
- LILRA2 | c.1320A>C p.Q440H (on ENST00000391738 / NM_001130917.3; = p.Q423H on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.382); catalogued as COSV52187724; called by muse, mutect2
- LIN7A | c.132A>C p.E44D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV54017493, COSV99691577, COSV99691982; called by muse, mutect2, varscan2
- LRFN5 | c.685A>G p.S229G | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV53241272; called by muse, mutect2, varscan2
- LRIG3 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.502); catalogued as COSV57860507; called by muse, mutect2, varscan2
- LRP1B | c.10337C>T p.T3446M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as rs748759183, COSV67182342; called by muse, mutect2, varscan2
- LRRIQ1 | c.4991T>G p.L1664R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as COSV67824830; called by mutect2, varscan2
- LRRK2 | c.1889T>G p.I630S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV100110468, COSV54141988; called by muse, mutect2, varscan2
- LYST | c.8332C>T p.R2778* | Nonsense Mutation (SNP) | VAF 39/111 reads (35%) | catalogued as rs1292631310, COSV67702767, COSV67707366; called by muse, mutect2, varscan2
- MAGEB3 | c.188A>G p.K63R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV64396690, COSV64397641; called by muse, mutect2
- MAGEC1 | c.1624T>C p.S542P | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); catalogued as COSV53567308; called by muse, mutect2, varscan2
- MAGEC3 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV53575632, COSV53580495; called by muse, mutect2, varscan2
- MAGI2 | c.1876C>G p.Q626E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62631338; called by muse, mutect2, varscan2
- MAP3K12 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 5/55 reads (9%) | catalogued as rs1186325896, COSV57230923; called by muse, mutect2
- MCF2 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MGAT4C | c.49A>G p.M17V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59829376; called by muse, mutect2
- MTR | c.2797A>C p.S933R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV63963716; called by muse, mutect2, varscan2
- MUC16 | c.28804A>G p.T9602A | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.07); catalogued as rs1323651449, COSV67441348; called by muse, mutect2, varscan2
- MUC16 | c.11967A>C p.Q3989H | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV67441357; called by muse, varscan2
- MUC16 | c.8567A>G p.E2856G | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV67441519; called by muse, mutect2, varscan2
- MYCT1 | c.163A>G p.S55G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV65890731, COSV65891152; called by muse, mutect2, varscan2
- MYH3 | c.2857A>G p.K953E | Missense Mutation (SNP) | VAF 90/305 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as COSV56860356; called by muse, mutect2, varscan2
- MYH6 | c.1352A>T p.K451M | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV62447598; called by muse, mutect2, varscan2
- MYO7B | c.2705G>A p.R902H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as rs373870541; called by muse, mutect2, varscan2
- NCOA2 | c.4285C>T p.P1429S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV51218291; called by muse, mutect2
- NEGR1 | c.786G>A p.K262= | Splice Region (SNP) | VAF 18/84 reads (21%) | catalogued as rs776347091, COSV60828847; called by muse, mutect2, varscan2
- NLRP13 | c.2116A>T p.S706C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as COSV61619663; called by muse, mutect2
- NLRP14 | c.1037A>C p.K346T | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV55063604, COSV55064199; called by muse, mutect2, varscan2
- NRG1 | c.1597C>T p.P533S (on ENST00000405005 / NM_013964.5; = p.P538S on NM_013956.5) | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.099); catalogued as COSV55147191; called by muse, mutect2, varscan2
- NRP1 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55178281; called by muse, mutect2
- NRXN1 | c.1552T>G p.L518V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs569617213, COSV58434387, COSV58487822; called by muse, mutect2, varscan2
- NUP153 | c.2942T>G p.F981C | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50446027; called by muse, mutect2, varscan2
- OR10G8 | c.302A>C p.Y101S | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV70908110; called by muse, mutect2, varscan2
- OR10T2 | c.854T>G p.L285R | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57780011; called by muse, mutect2, varscan2
- OR13F1 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV58250616; called by muse, mutect2, varscan2
- OR1L6 | c.122A>C p.N41T (on ENST00000373684; = p.N5T on NM_001004453.2) | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV59027747; called by muse, mutect2, varscan2
- OR2T5 | c.55A>C p.M19L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63540365; called by muse, mutect2, varscan2
- OR4C13 | c.455T>G p.L152R | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV73648601; called by muse, mutect2, varscan2
- OR4N2 | c.128T>G p.F43C | Missense Mutation (SNP) | VAF 30/178 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV60049765, COSV60051008; called by muse, mutect2, varscan2
- OR4S1 | c.88T>G p.F30V | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60678614; called by muse, mutect2, varscan2
- OR51F2 | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV59063553; called by muse, mutect2, varscan2
- OR52N1 | c.133T>G p.F45V | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.028); catalogued as COSV57692824; called by muse, mutect2, varscan2
- OR5D14 | c.289T>G p.F97V | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1400472819, COSV59455243; called by muse, mutect2
- OR5H15 | c.94T>G p.L32V | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV62947270; called by muse, mutect2, varscan2
- OR5J2 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56620082; called by muse, mutect2, varscan2
- OR5M11 | c.794A>T p.K265M | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV73141619, COSV73142032; called by muse, mutect2, varscan2
- OR5T3 | c.590T>A p.L197H | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57379289; called by muse, mutect2, varscan2
- OR6C3 | c.275A>C p.N92T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as COSV65570564, COSV65571575; called by muse, mutect2, varscan2
- OR6Y1 | c.680T>G p.L227R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV56928024; called by muse, mutect2, varscan2
- OR8J3 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100041072, COSV56879215, COSV56883780; called by muse, mutect2, varscan2
- OR8K1 | c.328T>G p.F110V | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as COSV54401231, COSV54401510; called by muse, mutect2, varscan2
- OSTN | c.194T>G p.L65R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59138640; called by muse, varscan2
- OVCH1 | c.2428A>G p.K810E | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV58958978; called by muse, mutect2, varscan2
- OVOL1 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs151272806; called by muse, mutect2, varscan2
- PASD1 | c.107T>G p.V36G | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV64853866; called by muse, mutect2
- PCDHB3 | c.874T>G p.F292V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as rs1554272309, COSV50563907; called by muse, mutect2, varscan2
- PCNX2 | c.5605A>T p.M1869L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50780757; called by muse, mutect2, varscan2
- PKHD1 | c.8338T>C p.F2780L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61858577; called by muse, mutect2, varscan2
- PLCXD3 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV60603926; called by muse, varscan2
- PLCXD3 | c.305A>G p.K102R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60603933, COSV60607243; called by muse, varscan2
- PPFIA2 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61018859; called by muse, mutect2, varscan2
- PPP1R3A | c.3081A>C p.E1027D | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV52875219; called by muse, mutect2, varscan2
- PREX2 | c.3266T>C p.V1089A | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as rs763886172, COSV55748813, COSV55751747; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.403A>T p.R135* (on ENST00000421990 / NM_001136042.2; = p.R117* on NM_025267.3) | Nonsense Mutation (SNP) | VAF 18/250 reads (7%) | catalogued as COSV64181600; called by muse, mutect2
- PTPRT | c.2314A>C p.R772= | Splice Region (SNP) | VAF 16/112 reads (14%) | catalogued as COSV61982822; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, varscan2
- RBMXL1 | c.4G>C p.V2L | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV99555941; called by mutect2, varscan2
- REPS2 | c.1759A>C p.S587R | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV58178275; called by muse, mutect2, varscan2
- RFX4 | c.1652C>T p.T551M (on ENST00000392842 / NM_213594.3; = p.T457M on NM_032491.6) | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1239999077, COSV57571599; called by muse, mutect2
- RIMS2 | c.4388T>C p.L1463P (on ENST00000666250 / NM_001348490.2; = p.L1034P on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51650054; called by muse, mutect2, varscan2
- RRM2B | c.700T>A p.F234I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52565349; called by muse, mutect2, varscan2
- RXFP3 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.433); catalogued as rs1222555257, COSV57503814, COSV57509176; called by muse, mutect2, varscan2
- RXRB | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 36/177 reads (20%) | catalogued as COSV63399428; called by muse, mutect2, varscan2
- RYR3 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66776310; called by muse, mutect2, varscan2
- SCN9A | c.1784A>G p.Q595R | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV57598667; called by muse, mutect2, varscan2
- SEC23B | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.611); catalogued as COSV52718139; called by muse, mutect2, varscan2
- SEMA3E | c.2249A>G p.K750R | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV57078008; called by muse, mutect2, varscan2
- SEMA6A | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746941869, COSV56709000; called by muse, mutect2, varscan2
- SEPHS1 | c.652-2A>T p.X218_splice | Splice Site (SNP) | VAF 8/117 reads (7%) | catalogued as COSV59256946; called by muse, mutect2
- SERPINA10 | c.842A>C p.K281T | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV56227351; called by muse, mutect2, varscan2
- SERPINB3 | c.1136A>C p.N379T | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV52189592; called by muse, mutect2, varscan2
- SETBP1 | c.328A>G p.T110A | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.829); catalogued as COSV56311958; called by muse, mutect2, varscan2
- SH3BP5 | c.889+1G>A p.X297_splice | Splice Site (SNP) | VAF 32/63 reads (51%) | catalogued as COSV53742751; called by muse, mutect2, varscan2
- SHISA2 | c.754G>A p.V252M | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.243); catalogued as COSV60110029; called by muse, mutect2, varscan2
- SIT1 | c.7C>G p.Q3E | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.058); catalogued as COSV52399521; called by muse, mutect2, varscan2
- SLC12A1 | c.1286T>C p.V429A | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs1034031225, COSV57707966; called by muse, mutect2, varscan2
- SLC25A2 | c.212T>G p.L71R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53402941; called by muse, mutect2, varscan2
- SLC4A10 | c.2843C>T p.S948L (on ENST00000446997 / NM_001354461.2; = p.S918L on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55762770; called by muse, mutect2, varscan2
- SLC8A3 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV63518646; called by muse, mutect2, varscan2
- SLCO1B1 | c.2036T>G p.F679C | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV57006538; called by muse, mutect2, varscan2
- SLCO2A1 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1187873219, COSV60483132; called by muse, mutect2
- SMG8 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs765179613, COSV56283532; called by muse, mutect2, varscan2
- SMO | c.1180T>C p.Y394H | Missense Mutation (SNP) | VAF 62/281 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50824113; called by muse, mutect2, varscan2
- SMTNL2 | c.749C>T p.T250M (on ENST00000389313 / NM_001114974.2; = p.T106M on NM_198501.3) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs745626976, COSV58806668; called by muse, mutect2, varscan2
- SNCAIP | c.2066A>C p.K689T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV54401213, COSV54414882; called by muse, mutect2, varscan2
- SOCS5 | c.557G>T p.G186V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60603573; called by muse, mutect2, varscan2
- SOHLH2 | c.254A>G p.K85R | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1190348020, COSV58520560, COSV58522859; called by muse, mutect2, varscan2
- SOX8 | c.851A>C p.E284A | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53508570; called by muse, mutect2, varscan2
- SP140 | c.1838A>C p.K613T | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV59445857; called by muse, mutect2, varscan2
- SPHKAP | c.1569A>C p.Q523H | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as COSV60867482; called by muse, mutect2, varscan2
- SPTA1 | c.6182A>C p.K2061T | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV63748194; called by muse, mutect2, varscan2
- SPTLC3 | c.1250T>G p.L417R | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV65463363; called by muse, mutect2, varscan2
- STK24 | c.1076T>G p.L359W | Missense Mutation (SNP) | VAF 42/185 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV64822232; called by muse, mutect2, varscan2
- SULT1C3 | c.490T>G p.L164V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1217929698, COSV61252245; called by muse, mutect2, varscan2
- SYNE1 | c.20206A>C p.K6736Q (on ENST00000367255 / NM_182961.4; = p.K6665Q on NM_033071.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV54896338; called by muse, mutect2
- SYNE1 | c.6924A>C p.Q2308H (on ENST00000367255 / NM_182961.4; = p.Q2315H on NM_033071.3) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54896386; called by muse, mutect2, varscan2
- SYT1 | c.883C>A p.L295M | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV54031137; called by muse, mutect2, varscan2
- TAF1L | c.4796T>G p.V1599G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.527); catalogued as COSV54256353; called by muse, mutect2, varscan2
- TAF1L | c.3113A>G p.K1038R | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV54256364, COSV54266410; called by muse, mutect2, varscan2
- TBC1D4 | c.582C>A p.D194E | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.173); catalogued as COSV66487387, COSV66489829; called by muse, mutect2
- TBL1X | c.1061T>G p.I354R | Missense Mutation (SNP) | VAF 69/130 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54273870; called by muse, mutect2, varscan2
- TBX18 | c.714A>C p.Q238H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63735914; called by muse, mutect2, varscan2
- TECTA | c.3134T>G p.L1045R | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as COSV50687603, COSV50687648; called by muse, mutect2, varscan2
- TF | c.978dup p.R327Qfs*11 | Frame Shift Ins (INS) | VAF 12/55 reads (22%) | catalogued as rs768975401; called by mutect2, varscan2
- THSD4 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 131/433 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs754915085, COSV55959700; called by muse, mutect2, varscan2
- TINAG | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.07); catalogued as rs201629982, COSV52505076; called by muse, varscan2
- TLL1 | c.2344A>C p.S782R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.421); catalogued as COSV50261105; called by muse, mutect2, varscan2
- TMC5 | c.569A>G p.H190R | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs370224630; called by muse, varscan2
- TMEM132B | c.3223C>G p.Q1075E | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.717); catalogued as COSV54742879; called by muse, mutect2
- TMPRSS15 | c.1624T>G p.F542V | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV53034112, COSV53041704; called by muse, mutect2, varscan2
- TNXB | c.12313G>A p.E4105K (on ENST00000647633; = p.E3858K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs758936240, COSV100926114; called by muse, mutect2, varscan2
- TRIM51 | c.1318T>C p.S440P | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV55263252; called by muse, mutect2, varscan2
- TRPC4 | c.2247A>C p.E749D (on ENST00000379705 / NM_016179.4; = p.E754D on NM_003306.3) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV58989064; called by muse, mutect2, varscan2
- TRPC4 | c.1781A>G p.E594G | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV58989092; called by muse, mutect2, varscan2
- TRPC6 | c.134A>G p.Q45R | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.033); catalogued as rs1424446928, COSV60250601; called by muse, mutect2
- TRRAP | c.4820A>T p.N1607I (on ENST00000359863 / NM_001244580.1; = p.N1589I on NM_003496.3) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV62837990; called by muse, mutect2, varscan2
- TRUB2 | c.365C>A p.A122D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV65759058; called by muse, varscan2
- TTN | c.40948A>C p.S13650R (on ENST00000591111; = p.S6226R on NM_003319.4) | Missense Mutation (SNP) | VAF 25/141 reads (18%) | PolyPhen possibly damaging (0.788); catalogued as COSV59864262, COSV59925441; called by muse, mutect2, varscan2
- TTN | c.13168G>A p.E4390K (on ENST00000591111; = p.E4344K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | PolyPhen benign (0.204); catalogued as rs749584249, COSV59864283; called by muse, mutect2, varscan2
- TYR | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM143572, COSV54469143; called by muse, mutect2, varscan2
- UNC13C | c.3014T>C p.I1005T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.261); catalogued as COSV52840127; called by muse, mutect2, varscan2
- UPK1A | c.288C>A p.Y96* | Nonsense Mutation (SNP) | VAF 54/203 reads (27%) | catalogued as COSV55877299; called by muse, mutect2, varscan2
- USH2A | c.5098A>C p.I1700L | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV56322322; called by muse, mutect2, varscan2
- VWA5A | c.1652A>G p.K551R | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.2); catalogued as COSV64411670; called by muse, mutect2, varscan2
- ZNF211 | c.493A>C p.S165R (on ENST00000347302 / NM_198855.4; = p.S178R on NM_006385.5) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.091); catalogued as COSV53739494; called by muse, mutect2, varscan2
- ZNF236 | c.1981T>C p.Y661H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53481567; called by muse, mutect2
- ZNF251 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs570734146, COSV52955676; called by muse, mutect2, varscan2
- ZNF329 | c.537T>G p.N179K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV63771570; called by muse, mutect2, varscan2
- ZNF460 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV64415291; called by muse, mutect2
- ZNF571 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs774576167, COSV60732173; called by muse, mutect2, varscan2
- ZNF606 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV100357407, COSV62044859; called by muse, mutect2, varscan2
- ZNF665 | c.398G>T p.R133I (on ENST00000600412; = p.R198I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV67213260, COSV67213942, COSV67217359; called by muse, mutect2, varscan2
- ZNF793 | c.62A>C p.E21A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV71324787; called by muse, mutect2
- ZNF813 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 20/215 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.71); catalogued as COSV67175557; called by muse, mutect2
- ZRANB3 | c.1399G>C p.G467R | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51492345; called by muse, mutect2, varscan2
- ZSWIM2 | c.1655A>C p.N552T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs776449986, COSV54573548; called by muse, mutect2, varscan2
- B4GALT6 | c.524del p.F175Sfs*4 | Frame Shift Del (DEL) | VAF 14/85 reads (16%) | called by mutect2, pindel, varscan2
- C6orf118 | c.25T>G p.L9V | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- IFT57 | c.685_686del p.I229Ffs*26 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by pindel, varscan2
- KCNB1 | c.1922del p.N641Tfs*21 | Frame Shift Del (DEL) | VAF 18/176 reads (10%) | called by mutect2, pindel, varscan2
- KLHL14 | c.1119_1121del p.F373del | In Frame Del (DEL) | VAF 6/36 reads (17%) | called by pindel, varscan2
- MRC1 | c.2851T>G p.F951V | Missense Mutation (SNP) | VAF 63/344 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYOM2 | c.3314T>C p.L1105P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH11X | c.2403_2404insC p.D802Rfs*7 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | called by mutect2, pindel*, varscan2
- PCDHGA12 | c.2145G>C p.R715S | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); called by muse, mutect2
- ZNF484 | c.1946del p.S649* | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.3363A>G p.T1121= | Silent (SNP) | VAF 10/212 reads (5%) | catalogued as COSV99484414; called by muse, mutect2
- ADGRV1 | c.7893T>C p.A2631= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV67977538; called by muse, varscan2
- AFTPH | c.1125T>A p.T375= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53215537; called by muse, mutect2, varscan2
- AMPH | c.1578A>G p.E526= | Silent (SNP) | VAF 49/177 reads (28%) | catalogued as COSV57731310; called by muse, mutect2, varscan2
- ANKRD55 | c.858G>A p.E286= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1044421914, COSV61943933; called by muse, mutect2
- APBA1 | c.1125A>G p.K375= | Silent (SNP) | VAF 44/134 reads (33%) | catalogued as rs774728152, COSV55221022; called by muse, mutect2, varscan2
- ARHGEF5 | c.4242G>A p.T1414= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs1456337849, COSV99282704; called by mutect2, varscan2
- CACNG2 | c.627G>A p.R209= | Silent (SNP) | VAF 39/364 reads (11%) | catalogued as COSV55631700; called by muse, mutect2, varscan2
- CBLIF | c.450C>T p.T150= | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV57237821; called by muse, mutect2, varscan2
- CLEC2B | c.418A>C p.R140= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57308531; called by muse, mutect2, varscan2
- CNTN3 | c.1845A>G p.Q615= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55161936, COSV99726459; called by muse, mutect2, varscan2
- CSMD3 | c.4693A>C p.R1565= (on ENST00000297405 / NM_001363185.1; = p.R1461= on NM_052900.3) | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV52091423; called by muse, mutect2, varscan2
- CTNND2 | c.1228T>C p.L410= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV58861735, COSV58895397; called by muse, mutect2, varscan2
- CYP2E1 | c.99C>T p.P33= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV53311918; called by muse, mutect2
- CYSLTR1 | c.306T>C p.A102= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV100964722, COSV64819279; called by muse, mutect2, varscan2
- DLG2 | c.165T>C p.F55= (on ENST00000650630 / NM_001351274.2; = p.F18= on NM_001142699.3) | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as COSV65821881, COSV65833079; called by muse, mutect2, varscan2
- DZIP1 | c.2406T>C p.S802= (on ENST00000347108; = p.S783= on NM_014934.5) | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as rs760051137, COSV61263617; called by muse, mutect2, varscan2
- EIF2AK4 | c.996G>A p.K332= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs1566988301, COSV55464364; called by muse, mutect2, varscan2
- ELMOD1 | c.447T>G p.T149= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1264715127, COSV56190340, COSV56190396; called by muse, mutect2, varscan2
- ENTPD6 | c.82A>C p.R28= | Silent (SNP) | VAF 7/174 reads (4%) | catalogued as COSV61750806; called by muse, mutect2
- EPB41L3 | c.2286C>T p.S762= | Silent (SNP) | VAF 31/109 reads (28%) | catalogued as COSV59442847; called by muse, mutect2, varscan2
- FREM2 | c.1402T>C p.L468= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as COSV54826828, COSV54842467; called by muse, mutect2, varscan2
- GFRAL | c.1125T>G p.T375= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100474895; called by muse, mutect2, varscan2
- GJB3 | c.483G>T p.L161= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as COSV64904361; called by muse, mutect2
- GLCCI1 | c.1512G>A p.T504= | Silent (SNP) | VAF 184/369 reads (50%) | catalogued as rs146979444; called by muse, mutect2, varscan2
- GLP2R | c.327T>G p.S109= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs920376781, COSV52321551; called by muse, mutect2, varscan2
- GRIN2A | c.1794T>G p.S598= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV58018335, COSV58049640; called by muse, mutect2, varscan2
- HARS1 | c.1245T>C p.S415= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV56905323; called by muse, mutect2
- IBSP | c.558A>G p.A186= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV56894474; called by muse, mutect2, varscan2
- ITGA4 | c.1737T>C p.A579= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV51997449; called by muse, mutect2, varscan2
- KCNC1 | c.861G>A p.L287= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV56391051, COSV56394195; called by muse, mutect2
- KCNC2 | c.1317T>C p.G439= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1565809694, COSV54361394, COSV54365534; called by muse, mutect2, varscan2
- KCNQ1 | c.471C>T p.F157= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV50099706; called by muse, mutect2, varscan2
- KMT2C | c.1164C>T p.C388= | Silent (SNP) | VAF 14/302 reads (5%) | catalogued as COSV51274804; called by muse, mutect2
- L3MBTL4 | c.1617A>G p.Q539= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as COSV53111923, COSV53123052; called by muse, mutect2, varscan2
- LCE1C | c.105T>G p.P35= | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV64218107; called by muse, mutect2, varscan2
- LIPF | c.858T>G p.T286= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV53282199; called by muse, mutect2
- LRRK2 | c.6180T>G p.G2060= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100110303, COSV54142008; called by muse, mutect2, varscan2
- MEIS1 | c.1167C>T p.Y389= | Silent (SNP) | VAF 49/188 reads (26%) | catalogued as COSV55482768; called by muse, mutect2, varscan2
- MPEG1 | c.1254G>A p.P418= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs374806906; called by muse, mutect2, varscan2
- MROH5 | c.645C>T p.G215= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs767794745, COSV71300297; called by muse, mutect2, varscan2
- NELL1 | c.595T>C p.L199= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV54235188; called by muse, mutect2, varscan2
- NEXMIF | c.603A>C p.S201= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV50021531; called by muse, mutect2, varscan2
- ODAM | c.771T>A p.A257= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as COSV68572209; called by muse, mutect2, varscan2
- OR2L2 | c.573T>C p.T191= | Silent (SNP) | VAF 76/256 reads (30%) | catalogued as COSV63547469; called by muse, mutect2, varscan2
- OR6X1 | c.898A>C p.R300= | Silent (SNP) | VAF 21/137 reads (15%) | catalogued as COSV60009248; called by muse, mutect2, varscan2
- PCDHB7 | c.1665C>T p.N555= | Silent (SNP) | VAF 94/224 reads (42%) | catalogued as rs782725222, COSV50753531, COSV99176308; called by muse, mutect2, varscan2
- PIDD1 | c.423G>A p.P141= | Silent (SNP) | VAF 19/105 reads (18%) | catalogued as rs1168472005, COSV61704021; called by muse, mutect2, varscan2
- PMP22 | c.315T>G p.L105= | Silent (SNP) | VAF 32/122 reads (26%) | catalogued as COSV56601153; called by muse, mutect2, varscan2
- PRAMEF20 | c.354A>G p.E118= | Silent (SNP) | VAF 88/409 reads (22%) | called by muse, mutect2, varscan2
- PRKCQ | c.1317G>A p.P439= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as rs748660677, COSV54105442; called by muse, mutect2, varscan2
- PRKN | c.234A>G p.Q78= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV58198493; called by muse, mutect2
- PRR18 | c.318C>G p.T106= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV59454037; called by muse, mutect2, varscan2
- PTPRZ1 | c.2871T>C p.T957= | Silent (SNP) | VAF 33/99 reads (33%) | catalogued as COSV66429410, COSV66438309; called by muse, mutect2, varscan2
- RBM46 | c.588T>C p.A196= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as rs892339422, COSV55976700; called by muse, mutect2, varscan2
- RNF19B | c.1539G>A p.T513= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as rs778802299, COSV52386650; called by muse, mutect2, varscan2
- SECISBP2L | c.3186G>A p.G1062= (on ENST00000559471 / NM_001193489.2; = p.G1017= on NM_014701.4) | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as COSV55932444; called by muse, mutect2, varscan2
- SERPINA9 | c.741T>G p.A247= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54072414, COSV54078284; called by muse, mutect2, varscan2
- SERTM1 | c.288C>G p.S96= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV59375573; called by muse, mutect2, varscan2
- SLC24A2 | c.30T>G p.T10= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as COSV53856404; called by muse, mutect2, varscan2
- SLC35F1 | c.1200A>G p.E400= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV64497953; called by muse, mutect2, varscan2
- SLITRK3 | c.2763A>G p.Q921= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV53845274; called by muse, mutect2, varscan2
- TNNI3K | c.2139T>G p.S713= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV53945431; called by muse, mutect2, varscan2
- TPPP | c.480G>T p.S160= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100862778, COSV62191065; called by muse, mutect2
- TTLL7 | c.393T>C p.T131= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53080981; called by muse, mutect2, varscan2
- UNC13C | c.2754A>G p.Q918= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV52840107; called by muse, mutect2, varscan2
- USP38 | c.1680T>G p.T560= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs759892270, COSV61024645; called by muse, mutect2, varscan2
- XRN2 | c.765C>T p.F255= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1306697702, COSV65867823, COSV65867828, COSV65868152; called by muse, mutect2, varscan2
- ZBED2 | c.366G>A p.Q122= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as COSV51912181; called by muse, mutect2
- ZCWPW2 | c.966A>G p.E322= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as COSV67497339; called by muse, mutect2, varscan2
- ZMIZ2 | c.1530C>G p.L510= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV54805696; called by muse, varscan2
- ZNF208 | c.1701C>A p.T567= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV68105341; called by mutect2, varscan2
- ZNF264 | c.1521A>G p.G507= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV54040469; called by muse, mutect2, varscan2
- AL590867.2 | n.32T>A | RNA (SNP) | VAF 10/144 reads (7%) | called by muse, mutect2
- CLLU1 | n.854A>G | RNA (SNP) | VAF 7/27 reads (26%) | catalogued as COSV101029272, COSV65903582; called by muse, mutect2, varscan2
- NALCN | c.1765-4857T>C | Intron (SNP) | VAF 24/131 reads (18%) | catalogued as COSV51922869, COSV51925386, COSV51970703; called by muse, mutect2, varscan2
- NXF5 | n.1456T>G | RNA (SNP) | VAF 16/80 reads (20%) | catalogued as COSV99534220; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1903C>T | Intron (SNP) | VAF 24/89 reads (27%) | catalogued as rs755040458, COSV100678374; called by muse, mutect2, varscan2
- TTN | c.10360+1999A>T | Intron (SNP) | VAF 16/66 reads (24%) | catalogued as COSV59864318; called by muse, mutect2, varscan2
